Somatic mutation profile of tumor specimen CDDP-ACMK-TTP1-A (aliquot CDDP-ACMK-TTP1-A-2-0-D-A572-36) from CDDP_EAGLE case CDDP-ACMK, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69 years.
Specimen CDDP-ACMK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9229c3b3-b58d-422f-a8c0-0875603e4294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACMK-NB1-A (Blood Derived Normal), aliquot CDDP-ACMK-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52b2e540-a01a-4d0a-b703-d8db29d852c0

The open-access MAF lists 281 somatic variants for this specimen: 183 protein-altering or splice-affecting, 57 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 57, Intron 21, Nonsense Mutation 9, 5'UTR 8, RNA 7, Frame Shift Del 7, Splice Site 5, 3'UTR 4, Splice Region 2, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 96/360 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADPRS | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1309944014; called by muse, mutect2, varscan2
- AHRR | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57082085; called by muse, mutect2, varscan2
- ALPK2 | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV64495300; called by muse, mutect2
- ARL5A | c.47-1G>T p.X16_splice | Splice Site (SNP) | VAF 44/218 reads (20%) | catalogued as COSV99706552; called by muse, mutect2, varscan2
- ASCL3 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV57941810; called by muse, mutect2, varscan2
- CARD17 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 66/382 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs781611501; called by muse, mutect2, varscan2
- CFAP47 | c.7203C>G p.I2401M | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.137); catalogued as COSV66217769; called by muse, mutect2, varscan2
- COL15A1 | c.2755C>T p.L919F | Missense Mutation (SNP) | VAF 66/392 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as rs770917512, COSV66641458; called by muse, mutect2, varscan2
- COL21A1 | c.1483A>T p.I495L | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1371677726; called by muse, mutect2, varscan2
- COL9A3 | c.872C>G p.P291R | Missense Mutation (SNP) | VAF 209/600 reads (35%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.704); catalogued as COSV59652118; called by muse, mutect2, varscan2
- CPNE4 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV101456817; called by muse, varscan2
- CYP4F8 | c.1290C>A p.N430K | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1376859995; called by muse, mutect2, varscan2
- DGAT1 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.101); catalogued as rs572761204; called by muse, mutect2, varscan2
- DLX5 | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.125); catalogued as COSV99756497; called by muse, mutect2, varscan2
- ELAVL1 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100688210; called by muse, mutect2, varscan2
- ESPN | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 63/491 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs750160430; called by muse, mutect2, varscan2
- FAM124B | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV66271951; called by muse, mutect2, varscan2
- FBLN2 | c.2489C>A p.T830K | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851156; called by muse, mutect2, varscan2
- FBXO24 | c.1000G>T p.D334Y (on ENST00000241071 / NM_033506.3; = p.D372Y on NM_012172.5) | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV53825009; called by muse, mutect2, varscan2
- FOCAD | c.4181T>C p.I1394T | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV58100464; called by muse, mutect2, varscan2
- FRMPD2 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142764597; called by muse, mutect2, varscan2
- GCSAML | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63577145; called by muse, mutect2, varscan2
- KCNE3 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100035661; called by muse, mutect2, varscan2
- KCNJ12 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59170055; called by muse, mutect2, varscan2
- KIAA1958 | c.2013G>T p.Q671H | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100515995; called by muse, mutect2, varscan2
- KNDC1 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1364114945; called by muse, mutect2, varscan2
- METTL21C | c.509T>A p.L170Q | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939930; called by muse, mutect2, varscan2
- MPRIP | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV104401277; called by mutect2, varscan2
- MYH1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 72/312 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs767731312, COSV56857388, COSV56858193; called by muse, mutect2, varscan2
- NF1 | c.4578-2A>T p.X1526_splice (on ENST00000358273 / NM_001042492.3; = p.X1505_splice on NM_000267.3) | Splice Site (SNP) | VAF 98/353 reads (28%) | catalogued as CS000877, CS001441, COSV62197923; called by muse, mutect2, varscan2
- NR5A1 | c.74A>G p.Y25C | Missense Mutation (SNP) | VAF 150/572 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM131877; called by muse, mutect2, varscan2
- NUP93 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.077); catalogued as COSV100360618; called by muse, mutect2, varscan2
- OR2T8 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60662238; called by muse, mutect2, varscan2
- OR4K14 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs774374038; called by muse, mutect2, varscan2
- PAM | c.243A>G p.I81M | Missense Mutation (SNP) | VAF 54/395 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as rs777241437; called by muse, mutect2, varscan2
- PCNX3 | c.4325A>G p.N1442S | Missense Mutation (SNP) | VAF 39/451 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs376100973; called by muse, mutect2
- PKP3 | c.944+2T>C p.X315_splice | Splice Site (SNP) | VAF 24/406 reads (6%) | catalogued as rs1401393210, COSV58985989; called by muse, mutect2
- PRKDC | c.3452G>T p.R1151L | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV58049383, COSV58052674; called by muse, mutect2, varscan2
- PRSS58 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 50/429 reads (12%) | catalogued as COSV73488421, COSV73488761; called by muse, mutect2, varscan2
- PUS7 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62677574; called by muse, mutect2, varscan2
- RYR2 | c.10249C>A p.Q3417K | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV63669307; called by muse, mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by muse, mutect2, varscan2
- SEL1L3 | c.2227G>A p.V743I | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs958381182; called by muse, mutect2, varscan2
- SEMA6A | c.2758T>A p.Y920N | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV56710438; called by muse, mutect2, varscan2
- SF3B2 | c.247A>T p.M83L | Missense Mutation (SNP) | VAF 73/310 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.267); catalogued as rs1251978060; called by muse, mutect2, varscan2
- SLC7A14 | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV51583828; called by muse, mutect2, varscan2
- SLITRK4 | c.2018A>T p.H673L | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62024719; called by muse, mutect2, varscan2
- SMARCA4 | c.4837C>T p.R1613W | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as rs1370639203; ClinVar: uncertain significance; called by muse, mutect2
- SYCP2L | c.1280G>C p.R427T | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV51652932; called by muse, mutect2, varscan2
- TP53BP2 | c.219A>T p.Q73H | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59067321; called by muse, mutect2, varscan2
- TRIM48 | c.557C>G p.A186G | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV70162264, COSV70162386; called by muse, mutect2, varscan2
- UBR5 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1204561709, COSV55288000; called by muse, mutect2
- URB1 | c.5332G>T p.D1778Y | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs184808667, COSV66958512; called by muse, mutect2, varscan2
- XYLT1 | c.2343del p.V782Sfs*31 | Frame Shift Del (DEL) | VAF 61/285 reads (21%) | catalogued as COSV54491663; called by mutect2, pindel, varscan2
- ZNF541 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1206467731; called by muse, mutect2
- ZNF578 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV69736260; called by muse, mutect2, varscan2
- ADAMTS2 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ADAMTS6 | c.3067G>A p.V1023I | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AGAP3 | c.2147C>T p.P716L (on ENST00000622464; = p.P752L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- AKR1C8P | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 59/319 reads (18%) | called by muse, mutect2, varscan2
- ALG2 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 90/647 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ANKRD7 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ARMC4 | c.2388T>A p.C796* | Nonsense Mutation (SNP) | VAF 162/716 reads (23%) | called by muse, mutect2, varscan2
- C17orf97 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 80/363 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CAMKK2 | c.679A>T p.R227W | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CCDC168 | c.11884G>T p.E3962* | Nonsense Mutation (SNP) | VAF 30/123 reads (24%) | called by muse, mutect2, varscan2
- CD200R1L | c.815A>T p.*272Lext*20 | Nonstop Mutation (SNP) | VAF 36/197 reads (18%) | called by muse, mutect2, varscan2
- CD248 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH19 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH9 | c.1281G>T p.M427I | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CERKL | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHAF1B | c.829C>G p.P277A | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLEC6A | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- COL5A2 | c.1978-1G>T p.X660_splice | Splice Site (SNP) | VAF 80/488 reads (16%) | called by muse, mutect2, varscan2
- COPS5 | c.241_259del p.M81Vfs*4 | Frame Shift Del (DEL) | VAF 64/476 reads (13%) | called by mutect2, pindel
- CWF19L1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHX37 | c.1570G>T p.A524S | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLX1 | c.213C>A p.Y71* | Nonsense Mutation (SNP) | VAF 60/268 reads (22%) | called by muse, mutect2, varscan2
- DNAH7 | c.3573G>T p.W1191C | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJA3 | c.*19del | Splice Region (DEL) | VAF 22/145 reads (15%) | called by mutect2, pindel, varscan2
- DPEP3 | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ENAM | c.1784G>T p.R595I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ENTPD4 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXOC2 | c.319_320del p.W107Gfs*2 | Frame Shift Del (DEL) | VAF 40/292 reads (14%) | called by pindel, varscan2
- FAM170B | c.212G>T p.W71L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- FAT4 | c.4672G>C p.G1558R | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FFAR2 | c.942G>T p.R314S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FGG | c.809A>G p.Y270C | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FIG4 | c.1409G>T p.C470F | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRAS1 | c.6239A>T p.H2080L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GALNT12 | c.235G>C p.G79R | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GALNT9 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- GDF9 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- GRIK5 | c.343-1G>T p.X115_splice | Splice Site (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- GRM8 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GZMB | c.253A>T p.T85S | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- HLX | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- HOXA6 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); called by muse, mutect2
- HPS6 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- HS3ST5 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- IARS1 | c.3786C>A p.F1262L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDO1 | c.1077C>A p.S359R | Missense Mutation (SNP) | VAF 116/388 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV1-3 | c.196T>A p.W66R | Missense Mutation (SNP) | VAF 136/417 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2
- IGKV1-12 | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 108/635 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGSF10 | c.887T>A p.L296Q | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IRS2 | c.535G>T p.G179W | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- KBTBD12 | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- KCNA4 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.047); called by muse, varscan2
- KIF1A | c.2864C>A p.P955H | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KIF2B | c.1726C>A p.L576I | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- KRT2 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 78/693 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- KRT28 | c.266C>A p.T89N | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LAG3 | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, varscan2
- LECT2 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 81/288 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LILRB2 | c.1741C>A p.Q581K | Missense Mutation (SNP) | VAF 73/436 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LPA | c.3554C>A p.T1185K | Missense Mutation (SNP) | VAF 60/313 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRRC24 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- LYPD3 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 63/292 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- MARK4 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MRPL39 | c.77T>A p.F26Y | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO18B | c.5443C>G p.Q1815E | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- MYO1A | c.2703G>T p.K901N | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NAV3 | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NLRC4 | c.1451C>A p.T484K | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NLRP8 | c.3050G>A p.C1017Y | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OBSL1 | c.5042C>A p.T1681K | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- OR10H4 | c.783C>A p.Y261* | Nonsense Mutation (SNP) | VAF 33/201 reads (16%) | called by muse, mutect2, varscan2
- OR10V1 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OR14K1 | c.260C>A p.T87N | Missense Mutation (SNP) | VAF 63/372 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR51B2 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- OR51D1 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 24/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- OR5T1 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR8I2 | c.59A>T p.H20L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAK2 | c.772G>T p.G258W | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH8 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 85/312 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PCDHB13 | c.1521C>A p.N507K | Missense Mutation (SNP) | VAF 248/1033 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PELI3 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.415); called by muse, mutect2
- PELP1 | c.1637G>T p.R546M | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PIP4K2C | c.1231C>G p.R411G | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLEKHH2 | c.161G>T p.R54L | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PPP1R42 | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PRAC1 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PSKH2 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- PTPRN2 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 34/363 reads (9%) | called by muse, mutect2
- PTPRO | c.3642C>A p.S1214R (on ENST00000281171 / NM_030667.3; = p.S1186R on NM_002848.4) | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PTPRQ | c.6765C>A p.D2255E (on ENST00000616559; = p.D2222E on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2
- PYGL | c.2325T>G p.F775L | Missense Mutation (SNP) | VAF 123/532 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RDH16 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- RNF10 | c.2142G>T p.Q714H | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- SDK1 | c.6402G>T p.E2134D | Missense Mutation (SNP) | VAF 132/713 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SIGIRR | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC12A5 | c.493T>A p.C165S (on ENST00000454036 / NM_001134771.2; = p.C142S on NM_020708.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SLC6A2 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 88/420 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SLC6A7 | c.1533G>A p.L511= | Splice Region (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- SMPD3 | c.1388_1391del p.H463Pfs*136 | Frame Shift Del (DEL) | VAF 35/216 reads (16%) | called by mutect2, pindel, varscan2
- SNX7 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SORL1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SPATA7 | c.413A>G p.E138G | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPIN1 | c.494G>T p.W165L | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SPN | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 85/292 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPTA1 | c.6496G>A p.A2166T | Missense Mutation (SNP) | VAF 299/748 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SREK1 | c.904del p.D302Tfs*50 | Frame Shift Del (DEL) | VAF 136/724 reads (19%) | called by mutect2, pindel, varscan2
- STARD13 | c.3176G>T p.C1059F (on ENST00000336934 / NM_001243476.3; = p.C941F on NM_052851.3) | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- STK11 | c.867_871del p.M289Ifs*27 | Frame Shift Del (DEL) | VAF 127/309 reads (41%) | called by mutect2, pindel, varscan2
- SULF2 | c.1427A>T p.K476M | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SV2C | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 73/404 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SYCP2L | c.1281G>T p.R427S | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE1 | c.11955G>T p.M3985I (on ENST00000367255 / NM_182961.4; = p.M3914I on NM_033071.3) | Missense Mutation (SNP) | VAF 54/407 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNRG | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX13C | c.2913del p.N972Tfs*69 | Frame Shift Del (DEL) | VAF 57/136 reads (42%) | called by mutect2, pindel, varscan2
- TFR2 | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 133/456 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR10 | c.2304G>T p.W768C | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM132B | c.2018A>T p.Q673L | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TNN | c.923A>C p.Q308P | Missense Mutation (SNP) | VAF 88/581 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.3182A>G p.H1061R | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- UGT3A2 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VSIG1 | c.908T>C p.L303P | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- XIRP2 | c.5153G>T p.G1718V (on ENST00000628543; = p.G1893V on NM_152381.6) | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.274); called by muse, varscan2
- XIRP2 | c.5245A>G p.T1749A (on ENST00000628543; = p.T1924A on NM_152381.6) | Missense Mutation (SNP) | VAF 48/296 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, varscan2
- ZFP57 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF229 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by mutect2, varscan2
- ZNF677 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AARD | c.138G>A p.Q46= | Silent (SNP) | VAF 86/430 reads (20%) | called by muse, mutect2, varscan2
- ANO6 | c.199C>A p.R67= | Silent (SNP) | VAF 67/270 reads (25%) | catalogued as COSV100262605; called by muse, mutect2, varscan2
- AOC1 | c.717C>T p.N239= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs756319025; called by muse, mutect2, varscan2
- AVL9 | c.1932A>G p.P644= | Silent (SNP) | VAF 86/329 reads (26%) | called by muse, mutect2, varscan2
- BAHCC1 | c.2397C>T p.H799= | Silent (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2, varscan2
- C6orf118 | c.774G>C p.T258= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV57820355; called by muse, mutect2, varscan2
- CBLIF | c.450C>T p.T150= | Silent (SNP) | VAF 47/614 reads (8%) | catalogued as COSV57237821; called by muse, mutect2
- CCDC148 | c.1590A>G p.Q530= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- CCDC168 | c.11883G>A p.Q3961= | Silent (SNP) | VAF 31/123 reads (25%) | called by muse, mutect2, varscan2
- CD200 | c.660T>C p.V220= (on ENST00000473539 / NM_001004196.3; = p.V195= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 54/387 reads (14%) | called by muse, mutect2, varscan2
- CHD8 | c.339G>A p.S113= | Silent (SNP) | VAF 34/323 reads (11%) | catalogued as rs1166832405, COSV67870820; called by muse, mutect2, varscan2
- CYP11B2 | c.186G>A p.E62= | Silent (SNP) | VAF 99/422 reads (23%) | called by muse, mutect2, varscan2
- DNAJB8 | c.231C>A p.G77= | Silent (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- DOCK1 | c.1557G>A p.Q519= | Silent (SNP) | VAF 101/429 reads (24%) | called by muse, mutect2, varscan2
- DOCK10 | c.5556C>T p.L1852= | Silent (SNP) | VAF 80/321 reads (25%) | called by muse, mutect2, varscan2
- DOCK2 | c.2229G>T p.V743= | Silent (SNP) | VAF 70/291 reads (24%) | called by muse, mutect2, varscan2
- DSG1 | c.1452A>G p.Q484= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- FAT3 | c.11112G>C p.A3704= | Silent (SNP) | VAF 60/237 reads (25%) | catalogued as COSV53127080; called by muse, mutect2, varscan2
- FCRL3 | c.642G>A p.Q214= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as COSV63841432, COSV63843885; called by muse, mutect2, varscan2
- FLG | c.4278C>G p.S1426= | Silent (SNP) | VAF 74/560 reads (13%) | called by muse, mutect2, varscan2
- GJA9 | c.1395T>A p.L465= | Silent (SNP) | VAF 54/275 reads (20%) | catalogued as COSV62532938; called by muse, mutect2, varscan2
- GPR18 | c.507C>G p.P169= | Silent (SNP) | VAF 59/297 reads (20%) | catalogued as rs774634231; called by muse, mutect2, varscan2
- GSK3B | c.858A>C p.P286= | Silent (SNP) | VAF 43/250 reads (17%) | called by muse, mutect2, varscan2
- ITSN1 | c.1317G>T p.R439= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as rs1243426439; called by muse, mutect2, varscan2
- KIF1A | c.2865C>A p.P955= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs1553630541, COSV100241957; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL14 | c.690C>A p.P230= | Silent (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- KRT19 | c.1107C>A p.I369= | Silent (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- MAGEL2 | c.1986G>A p.Q662= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- MERTK | c.1410G>T p.G470= | Silent (SNP) | VAF 156/579 reads (27%) | called by muse, mutect2, varscan2
- MUC6 | c.987C>A p.S329= | Silent (SNP) | VAF 47/178 reads (26%) | called by muse, mutect2, varscan2
- MYO7A | c.3015G>T p.A1005= | Silent (SNP) | VAF 150/561 reads (27%) | catalogued as COSV101289256; called by muse, mutect2, varscan2
- NPHS2 | c.180C>A p.P60= | Silent (SNP) | VAF 112/539 reads (21%) | catalogued as COSV100858217; called by muse, mutect2, varscan2
- OR4X1 | c.285C>T p.C95= | Silent (SNP) | VAF 64/231 reads (28%) | called by muse, mutect2, varscan2
- OR5H14 | c.114C>A p.T38= | Silent (SNP) | VAF 56/401 reads (14%) | catalogued as COSV71194020; called by muse, mutect2, varscan2
- PAPPA | c.3087A>G p.V1029= | Silent (SNP) | VAF 33/250 reads (13%) | catalogued as rs761838902; called by muse, mutect2, varscan2
- PCDHB10 | c.2133G>T p.V711= | Silent (SNP) | VAF 68/188 reads (36%) | called by mutect2, varscan2
- PCDHB5 | c.1755G>T p.V585= | Silent (SNP) | VAF 307/1187 reads (26%) | called by muse, mutect2, varscan2
- PDE10A | c.2064G>A p.T688= | Silent (SNP) | VAF 38/316 reads (12%) | catalogued as rs375839208; called by muse, mutect2, varscan2
- PPP6R1 | c.2430G>C p.G810= | Silent (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- RALYL | c.465G>T p.P155= | Silent (SNP) | VAF 48/149 reads (32%) | catalogued as rs370262365; called by muse, mutect2, varscan2
- RRAGD | c.495C>T p.A165= | Silent (SNP) | VAF 39/235 reads (17%) | called by muse, mutect2, varscan2
- RUFY4 | c.1602G>T p.R534= | Silent (SNP) | VAF 48/198 reads (24%) | called by muse, varscan2
- RYR1 | c.6570C>T p.V2190= | Silent (SNP) | VAF 70/440 reads (16%) | called by muse, mutect2, varscan2
- RYR2 | c.6820C>T p.L2274= | Silent (SNP) | VAF 147/477 reads (31%) | catalogued as COSV63684966; called by muse, mutect2, varscan2
- SEZ6L2 | c.231G>A p.T77= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs192429917; called by muse, mutect2
- SFI1 | c.495G>T p.V165= | Silent (SNP) | VAF 66/193 reads (34%) | catalogued as COSV66292077; called by muse, mutect2, varscan2
- SHE | c.597C>T p.I199= | Silent (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.970C>A p.R324= | Silent (SNP) | VAF 42/338 reads (12%) | catalogued as COSV59482247; called by muse, varscan2
- SLITRK5 | c.1920G>T p.A640= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as COSV100281276; called by muse, mutect2, varscan2
- SOAT2 | c.1002T>A p.R334= | Silent (SNP) | VAF 21/201 reads (10%) | called by muse, mutect2
- SPATA31A1 | c.3819C>A p.L1273= | Silent (SNP) | VAF 76/410 reads (19%) | called by mutect2, varscan2
- STXBP5L | c.381C>A p.V127= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as rs1266360076, COSV56511529; called by muse, mutect2, varscan2
- SYT14 | c.36A>T p.V12= | Silent (SNP) | VAF 141/426 reads (33%) | called by muse, mutect2, varscan2
- TECPR1 | c.3198G>T p.P1066= | Silent (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1059C>A p.I353= | Silent (SNP) | VAF 43/137 reads (31%) | called by muse, mutect2, varscan2
- TRPV4 | c.2514G>T p.P838= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as COSV55681490, COSV99924688; called by muse, mutect2, varscan2
- TTN | c.74922A>C p.P24974= (on ENST00000591111; = p.P17550= on NM_003319.4) | Silent (SNP) | VAF 31/394 reads (8%) | called by muse, mutect2
- AC006288.1 | n.105C>A | RNA (SNP) | VAF 18/106 reads (17%) | catalogued as rs1290771288; called by muse, varscan2
- AC104472.1 | n.229G>A | RNA (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8719T>A | Intron (SNP) | VAF 82/302 reads (27%) | called by muse, mutect2, varscan2
- ADAM3A | n.2205A>T | RNA (SNP) | VAF 73/147 reads (50%) | called by muse, mutect2, varscan2
- ADK | c.66-23907G>T | Intron (SNP) | VAF 74/276 reads (27%) | called by muse, mutect2, varscan2
- BOD1P2 | n.460C>A | RNA (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- BOD1P2 | n.459C>A | RNA (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- C16orf82 | c.-66T>A | 5'UTR (SNP) | VAF 91/376 reads (24%) | catalogued as rs751471617; called by muse, mutect2, varscan2
- CAPN11 | c.16+2937_16+2938del | Intron (DEL) | VAF 28/182 reads (15%) | called by pindel, varscan2
- CCL4L2 | c.192-30del | Intron (DEL) | VAF 55/225 reads (24%) | called by mutect2, pindel, varscan2
- CDKL1 | c.367-800A>T | Intron (SNP) | VAF 64/276 reads (23%) | called by muse, mutect2, varscan2
- CNGA1 | c.-15+10490T>G | Intron (SNP) | VAF 27/384 reads (7%) | catalogued as rs1197725004, COSV104422602; called by muse, mutect2
- COL5A2 | c.2391+28G>T | Intron (SNP) | VAF 89/355 reads (25%) | called by muse, mutect2, varscan2
- COLEC11 | c.328+919A>G | Intron (SNP) | VAF 104/421 reads (25%) | called by muse, mutect2, varscan2
- EBF2 | c.1528+188C>T | Intron (SNP) | VAF 36/172 reads (21%) | called by muse, mutect2, varscan2
- FGF14 | c.608-47T>A | Intron (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
- HDGFL2 | c.1328+727C>G | Intron (SNP) | VAF 32/154 reads (21%) | called by muse, mutect2, varscan2
- HERC2P4 | n.163G>T | RNA (SNP) | VAF 147/305 reads (48%) | called by muse, mutect2, varscan2
- IL18R1 | c.468+1859A>T | Intron (SNP) | VAF 47/163 reads (29%) | called by muse, mutect2, varscan2
- KIAA1958 | chr9:112484488 G>A | 5'Flank (SNP) | VAF 24/344 reads (7%) | catalogued as rs1036989201; called by muse, mutect2
- NEK10 | c.2091-13298C>A | Intron (SNP) | VAF 43/179 reads (24%) | called by muse, mutect2, varscan2
- PADI4 | c.340+335C>A | Intron (SNP) | VAF 16/110 reads (15%) | called by muse, varscan2
- PEX19 | c.*211A>G | 3'UTR (SNP) | VAF 282/723 reads (39%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*445G>T | 3'UTR (SNP) | VAF 142/603 reads (24%) | called by muse, mutect2, varscan2
- PRKAA2 | c.-43A>T | 5'UTR (SNP) | VAF 28/121 reads (23%) | called by muse, varscan2
- PSD3 | c.-10G>T | 5'UTR (SNP) | VAF 72/224 reads (32%) | called by muse, mutect2, varscan2
- REG3A | c.76+9G>A | Intron (SNP) | VAF 45/186 reads (24%) | called by muse, mutect2, varscan2
- SCG5 | c.543+82G>T | Intron (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- SHISA9 | c.-108C>A | 5'UTR (SNP) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- SP8 | c.-178T>C | 5'UTR (SNP) | VAF 137/482 reads (28%) | called by muse, mutect2, varscan2
- STK10 | c.*11G>C | 3'UTR (SNP) | VAF 62/339 reads (18%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.-506C>A | 5'UTR (SNP) | VAF 38/70 reads (54%) | called by muse, varscan2
- TEPSIN | c.527-389G>T | Intron (SNP) | VAF 62/212 reads (29%) | catalogued as rs1033953731; called by muse, mutect2, varscan2
- TLN2 | c.-36-8727G>T | Intron (SNP) | VAF 95/323 reads (29%) | called by muse, mutect2, varscan2
- TRPA1 | c.-38G>T | 5'UTR (SNP) | VAF 79/314 reads (25%) | catalogued as COSV100084505; called by muse, mutect2, varscan2
- VAMP7 | c.*122A>T | 3'UTR (SNP) | VAF 96/423 reads (23%) | catalogued as COSV99387825; called by muse, mutect2, varscan2
- YIF1A | c.735+29T>C | Intron (SNP) | VAF 38/149 reads (26%) | called by muse, mutect2, varscan2
- ZNF670 | c.-13C>T | 5'UTR (SNP) | VAF 30/223 reads (13%) | catalogued as rs746588215; called by muse, mutect2, varscan2
- ZNF710 | c.1825+140T>A | Intron (SNP) | VAF 82/237 reads (35%) | called by muse, mutect2, varscan2
- ZNF772 | c.72+88del | Intron (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel, varscan2
- ZNF849P | n.1121A>C | RNA (SNP) | VAF 52/270 reads (19%) | called by muse, varscan2
